Gene-level copy-number profile of tumor specimen TCGA-DM-A0XD-01A from TCGA case TCGA-DM-A0XD, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.6 years (23,966 days).
Specimen TCGA-DM-A0XD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.8dc1e554-abe5-4d32-810d-7616ce4a0973.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A0XD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3472f220-ec3f-4ecc-a2cc-9ac65bb13f39

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,573; copy number 2: 50,200; copy number 3: 7,989; copy number 4: 41; copy number 6: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A0XD-01A-12D-A151-01): tumor purity 0.66, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,690,719, 3 genes: AC104164.2, MIR548BB, PPIAP70.
- chr7:90,590,619–90,597,353, 1 gene: AC002456.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,578,473–127,636,867, 1 gene, copy number 6 (within-gene range 2–6): AC104370.1.
- chr13:73,036,401–73,113,018, 4 genes, copy number 6: PSMD10P3, KLF5, FABP5P1, RNU6-66P.

Autosomal genes at a single copy (total copy number 1): 1,573. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
